Somatic mutation profile of tumor specimen TCGA-XE-AAOJ-01A (aliquot TCGA-XE-AAOJ-01A-12D-A435-10) from TCGA case TCGA-XE-AAOJ, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 24.8 years (9,046 days).
Specimen TCGA-XE-AAOJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b9eb40b-5128-4ce4-b6c9-ec75635b3230.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XE-AAOJ-10A (Blood Derived Normal), aliquot TCGA-XE-AAOJ-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f508a833-af49-4123-ab70-20d7def42dd8

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 6, Nonsense Mutation 2, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.14762C>G p.A4921G | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV68946407; called by muse, mutect2, varscan2
- ATP7B | c.3236G>A p.C1079Y | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM117984; called by muse, mutect2, varscan2
- CYP2D7 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs751454524; called by muse, mutect2, varscan2
- EVPLL | c.732C>A p.D244E | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.989); catalogued as COSV67684931, COSV67684996; called by muse, mutect2, varscan2
- PDHA2 | c.496G>A p.G166S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs755461904, COSV54777743; called by muse, mutect2, varscan2
- SLC26A6 | c.2251G>A p.D751N | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs772615123; called by muse, mutect2, varscan2
- A2M | c.1051T>G p.S351A | Missense Mutation (SNP) | VAF 19/292 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.146); called by muse, mutect2
- ANKRD30A | c.1743T>G p.C581W (on ENST00000611781; = p.C525W on NM_052997.2) | Missense Mutation (SNP) | VAF 30/516 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.201); called by muse, mutect2
- ANKRD30A | c.2457T>G p.C819W (on ENST00000611781; = p.C763W on NM_052997.2) | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); called by mutect2, varscan2
- CLP1 | c.316C>T p.Q106* | Nonsense Mutation (SNP) | VAF 28/97 reads (29%) | called by muse, mutect2, varscan2
- DNAH6 | c.4432A>C p.K1478Q | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOCK7 | c.4192G>T p.E1398* (on ENST00000635253 / NM_001367561.1; = p.E1367* on NM_033407.3) | Nonsense Mutation (SNP) | VAF 31/107 reads (29%) | called by muse, mutect2, varscan2
- LRRC7 | c.2811del p.N938Ifs*36 (on ENST00000651989 / NM_001370785.2; = p.N905Ifs*36 on NM_001330635.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 44/154 reads (29%) | called by mutect2, pindel, varscan2
- MTMR3 | c.2602C>T p.L868F | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- PRR4 | c.356T>C p.F119S | Missense Mutation (SNP) | VAF 26/271 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2
- CENPBD1 | c.78C>A p.L26= | Silent (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- HAPLN2 | c.969C>T p.G323= | Silent (SNP) | VAF 40/105 reads (38%) | catalogued as rs1015636415; called by muse, mutect2, varscan2
- IL17RA | c.825G>T p.G275= | Silent (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- NLRC4 | c.624C>A p.A208= | Silent (SNP) | VAF 34/109 reads (31%) | called by muse, mutect2, varscan2
- REEP6 | c.405G>A p.L135= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs1443475666; called by muse, mutect2, varscan2
- TMC4 | c.1050G>A p.L350= (on ENST00000617472 / NM_001145303.3; = p.L344= on NM_144686.4) | Silent (SNP) | VAF 20/60 reads (33%) | called by muse, mutect2, varscan2
- SERPINE2 | c.-23+556G>T | Intron (SNP) | VAF 19/71 reads (27%) | called by muse, mutect2, varscan2
